Somatic mutation profile of tumor specimen BA2461D (aliquot aq-BA2461D) from BEATAML1.0 case 2025, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.3 years (24,224 days).
Specimen BA2461D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 192cc335-d98a-4e6a-8631-f133acd373a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2285D (Solid Tissue Normal), aliquot aq-BA2285D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de20dfef-28b9-42b0-95a0-9a628ea9d780

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: RNA 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED24 | c.1716G>T p.M572I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- COL6A4P1 | n.342G>T | RNA (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
